HCMI case HCM-WCMC-1284-C67 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e4ff1639-9acf-43ee-87e7-207066dcd907

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age: 90 years or older (exact value withheld by GDC); Vital status: Dead; Days to death: 0 days.

Diagnoses (1)
1. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); AJCC staging edition: 8th; AJCC pathologic T: T1; AJCC pathologic N: N0; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 11; Lymphatic invasion present: No.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: BCG Vaccine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 0 days; Days to treatment end: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 0 days; Days to treatment end: 0 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (1 entry)
- Days to follow up: 0 days; Disease response: Progressive Disease; Progression or recurrence: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 63 kg; Height: 170.2 cm; BMI: 22.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-1284-C67-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample HCM-WCMC-1284-C67-11A: Sample type: Slides; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-1284-C67-11A-01-TS1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
  Slide HCM-WCMC-1284-C67-11A-01-BS1-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample HCM-WCMC-1284-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
